CCDI case PBCNSI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/87e781d5-e9d7-4d8a-857c-cf41656b7ecd

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.6 years (6,419 days).

Biospecimens (3 samples)
- Sample 0DWKFY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWKGT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWKGZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
